Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA1V, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA1V-06B (Metastatic).

[page 1 of 3]
ICD-O-3
Melanoma NOS 8720/3
Site lymph node axilla C77.3
JW 4/2/14

CLINICAL HISTORY

Left axillary lymphadenopathy, atypical melanocytic lesion removed from back in

GROSS DESCRIPTION

1. Labeled "left axillary contents": The specimen consists of skin and deep subcutaneous tissue measuring 23 x 22 x 12 cm. On one surface there is a skin ellipse measuring 16 x 7 cm which is clear, although there is increased wrinkling and skin markings. Most of the specimen is composed of a large tumor which measures 14 cm in diameter. In addition there are smaller satellites of tumor in the deep portions of the specimen. Approximately 80% of the tumor is necrotic. Additional satellite tumor nodules measure up to 5 cm. Some are necrotic with the appearance of the main mass, and others are smooth encephaloid light brown. There are also multiple small brown grossly benign lymph nodes. Sampled as 1A-1C - large mass, 1D - axillary vein, 1E - satellite tumor mass, 1F - one satellite node, 1G - two satellite nodes, 1H - two satellite nodes, 1I - one satellite node, 1J - multiple satellite nodes, 1K - skin. 1L-1N additional encephaloid satellite tumor.
2. Labeled "supra-axillary lymph node": The specimen consists of multiple pieces of fat pad varying in size from 1.0 up to 4.0 cm. There is a soft brown lymph node measuring 0.7 cm. No additional lymph nodes are identified. Sampled as 2A - lymph nodes, 2B - fat.
3. Labeled "left supra-axillary lymph node for frozen section": The specimen consists of a 1.3 cm chocolate brown lymph node. Entirely embedded in cassette 3FSA.

INTRAOPERATIVE CONSULTATION (FS): - Benign lymph node.

4. Labeled "level II and III left axillary lymph nodes": The specimen consists of a triangular fat measuring 5.0 cm. It contains multiple soft brown lymph nodes. Cut sections are smooth brown and they appear benign. Sampled as 4A - two lymph nodes bisected, 4B - remaining lymph nodes.
5. Labeled "left subscapularis lymph nodes": The specimen consists of a fat pad measuring 6 cm. No lymph nodes are identified on gross exam. Sampled in cassette 5A.
- Microscopic sections are prepared and interpreted.

[page 2 of 3]
MICROSCOPIC

Tumor has a mixed spindle and epithelioid pattern. It is found in irregular whorls and fascicles. Tumor cells are large, hyperchromatic, and sometimes multinucleated. There are occasional nuclear pseudoinclusions, and frequent mitotic figures, some of which are abnormal. Immunostain for S100 protein is strongly positive in almost all tumor cells. Immunostain for HMB-45 shows focal weak staining in less than 5% of the tumor cells.

DIAGNOSIS

1. LABELED "LEFT AXILLARY CONTENTS".
- METASTATIC MALIGNANT MELANOMA (14 CM DIAMETER).
- APPROXIMATELY 80% OF TUMOR IS NECROTIC.
- METASTATIC MALIGNANT MELANOMA WITHIN MULTIPLE ADDITIONAL LARGE LYMPH NODES.
- THIRTEEN ADDITIONAL LYMPH NODES ARE BENIGN.
- UNREMARKABLE LEFT AXILLARY SKIN.
- AJCC PATHOLOGIC STAGING T1 N2a.
2. LABELED "BIOPSY OF SUPRAAXILLARY LYMPH NODE".
- THREE BENIGN LYMPH NODES.
3. LABELED "BIOPSY OF LEFT SUPRAAXILLARY LYMPH NODE FOR FROZEN SECTION".
- ONE BENIGN LYMPH NODE.
4. LABELED "LEVEL II AND LEVEL III LEFT AXILLARY LYMPH NODES".
- SIX BENIGN LYMPH NODES.
5. LABELED "LEFT SUBSCAPULARIS LYMPH NODE".
- FIBROADIPOSE TISSUE.
- LYMPH NODES ARE NOT IDENTIFIED.

ADDENDUM

ADDENDUM NUMBER ONE

Additional sections were submitted in cassettes 10 and 1P of the enlarged lymph nodes suspected to contain metastatic malignant melanoma. Four of these five additional lymph nodes contain metastatic melanoma. Therefore, diagnosis 1 is revised as follows:

DIAGNOSIS:

1. LABELED "LEFT AXILLARY CONTENTS":
- METASTATIC MALIGNANT MELANOMA WITHIN FIVE OF NINETEEN LYMPH NODES.
- LARGEST METASTASIS IS A BULKY MASS MEASURING 14 CM DIAMETER.
- APPROXIMATELY 80 PERCENT OF BULKY TUMOR MASS IS NECROTIC.
- UNREMARKABLE LEFT AXILLARY SKIN.
- AJCC PATHOLOGIC STAGING T1 N2a.

[page 3 of 3]
Signed Electronically signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 3a7ec85f-d19f-4946-a06b-c9fe3f58cf0c (TCGA-W3-AA1V.11DF82C1-C746-4D00-9119-1FEBE3FBC0A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).